Gene-level copy-number profile of tumor specimen TCGA-H8-A6C1-01A from TCGA case TCGA-H8-A6C1, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,677 days).
Specimen TCGA-H8-A6C1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.1b12e8a4-bff4-48c7-a968-f849b69f820d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-H8-A6C1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0adf2c2-c79b-4ae1-88b3-64ce0bbc4c5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 10,285; copy number 2: 45,712; copy number 3: 3,134; copy number 4: 187; copy number 5: 264; copy number 6: 110; copy number 14: 8; copy number 15: 6; copy number 18: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-H8-A6C1-01A-11D-A32M-01): tumor purity 0.42, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:167,400,495–167,742,287, 4 genes: RN7SL776P, PHBP14, RN7SKP188, AC105148.1.
- chr9:19,926,094–23,438,700, 73 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 413 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,099,624–151,325,605, 6 genes, copy number 15 (within-gene range 1–15): RPS3A, SNORD73B, SH3D19, SNORD73A, AC095055.1, AC104819.1.
- chr4:152,320,544–153,415,118, 24 genes, copy number 14–18 (within-gene range 1–18): FBXW7, FBXW7-AS1, AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4, ARFIP1, NSA2P6, FAM192BP, AC093599.2, FHDC1, AC093599.1, TRIM2, AC013477.1, RNU6-1196P, Y_RNA, ANXA2P1, MND1, RN7SL419P.
- chr4:154,724,586–156,006,988, 34 genes, copy number 6–18: NDUFB2P1, AC009567.1, AC009567.2, RBM46, RNU2-66P, RNU2-44P, AC097467.3, AC104407.1, NPY2R, AC097467.1, MAP9, YWHAEP4, AC097467.2, AC097467.4, AC097526.1, MTCYBP17, MTND6P17, MTND5P9, MTND4P8, MTND3P3, MTCO3P9, MTATP6P9, MTCO2P9, MTCO1P9, MTND2P33, MTND1P22, AC107208.1, GUCY1A1, AC104083.1, GUCY1B1, ASIC5, TDO2, CTSO, FTH1P21.
- chr6:19,323,428–19,839,080, 1 gene, copy number 5 (within-gene range 1–5): LNC-LBCS.
- chr6:19,438,283–19,842,197, 5 genes, copy number 5: RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4.
- chr9:29,636,486–29,636,853, 1 gene, copy number 6: AL354676.1.
- chr9:34,957,608–36,487,548, 78 genes, copy number 5 (broad region; genes not listed).
- chr17:49,788,648–51,521,401, 84 genes, copy number 6 (broad region; genes not listed).
- chr18:47,390–2,049,510, 46 genes, copy number 5 (within-gene range 3–5): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:1,927,727–1,929,094, 1 gene, copy number 5: AIDAP3.
- chr18:20,946,906–27,595,164, 133 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,873. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
